Gene-level copy-number profile of tumor specimen TCGA-BM-6198-01A from TCGA case TCGA-BM-6198, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-BM-6198-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.dcb25b9f-416c-493a-9010-59c1caf52447.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BM-6198-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/d8ae6155-e0c8-4d3f-89da-05975d3877aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,430; copy number 1: 23,483; copy number 2: 31,306; copy number 3: 3,014; copy number 5: 28.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,719,517–22,719,598, 1 gene: MIR4684.
- chr8:150,584–5,142,707, 69 genes (broad region; genes not listed).
- chr16:89,443,318–89,459,437, 2 genes: RNU6-430P, AC092120.2.
- chr17:1,344,275–1,400,222, 2 genes (within-gene range 0–1): YWHAE, AC032044.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:35,207,884–35,284,146, 1 gene, copy number 5 (within-gene range 2–5): AC023824.3.
- chr16:35,232,412–35,522,465, 27 genes, copy number 5: FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP.

Autosomal genes at a single copy (total copy number 1): 23,451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
